TCGA case TCGA-06-A5U0 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/603d2b61-b636-4054-ac95-ab66dabb3b48

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 21 years; Vital status: Alive.

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.4; Tissue or organ of origin: Occipital lobe; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 21.8 years (7,958 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 31 days; Days to treatment end: 74 days; Treatment dose: 6,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 31 days; Days to treatment end: 74 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 122 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Days to treatment start: 129 days; Treatment outcome: Treatment Ongoing.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 22.1 years (8,058 days); Days to diagnosis: 100 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 22.1 years (8,058 days); Days to diagnosis: 100 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 100 (post initial treatment): Progression or recurrence: Yes; Days to progression: 100 days; Days to recurrence: 100 days.
- Days to follow up: 143 days; Disease response: With Tumor.
- Days to follow up: 815 days (2.2 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-A5U0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 390 mg.
  Slide TCGA-06-A5U0-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-06-A5U0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 815 days; disease-specific survival: no event (censored), 815 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 100 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-A5U0-01A-11D-A33S-01): tumor purity 0.89, ploidy 3.84, whole-genome doublings 1.
